Gene-level copy-number profile of tumor specimen ALCH-B25S-TTP1-A from ALCHEMIST case ALCH-B25S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.8 years (25,481 days).
Specimen ALCH-B25S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74830215-b07b-424c-a524-4d437809d1db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B25S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/97478235-0fa4-4bc7-838e-f0cb1ddc0cba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 5,388; copy number 2: 52,049; copy number 3: 754; copy number 4: 109; copy number 5: 4; copy number 6: 1; copy number 8: 1; copy number 11: 1; copy number 17: 3.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,525,187–43,623,666, 1 gene: PTPRF.
- chr2:91,578,478–91,621,421, 3 genes (within-gene range 0–2): AC233266.1, AC233266.2, AC116050.1.
- chr4:49,502,145–49,557,400, 7 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr7:76,461,676–76,541,459, 8 genes: DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr9:33,383,179–33,402,682, 1 gene: AQP7.
- chr9:93,955,597–93,959,140, 1 gene: BARX1-DT.
- chr12:30,926,428–31,015,806, 3 genes: TSPAN11, AC008013.1, AC008013.2.
- chr15:25,174,927–25,225,284, 28 genes (within-gene range 0–1): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:16,441,577–16,492,193, 1 gene (within-gene range 0–1): LRRC75A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,087,351–242,175,634, 5 genes, copy number 5–6: AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr14:105,583,731–105,588,395, 1 gene, copy number 8: IGHA2.
- chr21:43,053,191–43,076,943, 1 gene, copy number 17: CBS.
- chr21:43,107,942–43,168,646, 2 genes, copy number 11–17 (within-gene range 4–17): AP001631.2, MRPL51P2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 17: AP001631.1.

Autosomal genes at a single copy (total copy number 1): 4,516. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
